Somatic mutation profile of tumor specimen MP2PRT-PAVRLX-TMP1-A (aliquot MP2PRT-PAVRLX-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVRLX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (933 days).
Specimen MP2PRT-PAVRLX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8869f4ed-abeb-4bae-a37e-942f9bf7ddc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVRLX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVRLX-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/929c96b4-0a25-4ff6-b847-9b14e9c639a1

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Nonsense Mutation 2, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC198 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.112); catalogued as rs745990428; called by muse, mutect2, varscan2
- IGFL2 | c.107C>T p.P36L (on ENST00000377693 / NM_001135113.2; = p.P47L on NM_001002915.2) | Missense Mutation (SNP) | VAF 35/421 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs750505405; called by muse, mutect2
- KRTAP8-1 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 225/427 reads (53%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.05); catalogued as rs1156387848, COSV61598577; called by muse, mutect2, varscan2
- SRRM3 | c.1840G>A p.G614S | Missense Mutation (SNP) | VAF 67/727 reads (9%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.116); catalogued as rs888739251, COSV58388422; called by muse, mutect2
- CDC14B | c.361T>G p.F121V | Missense Mutation (SNP) | VAF 134/264 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- DUSP4 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 310/692 reads (45%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IGHV4-61 | c.353_354insGATGAG | In Frame Ins (INS) | VAF 58/212 reads (27%) | called by pindel, varscan2
- YLPM1 | c.4721G>A p.W1574* | Nonsense Mutation (SNP) | VAF 196/418 reads (47%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 50/690 reads (7%) | called by muse, mutect2
- AP5B1 | c.717A>G p.A239= | Silent (SNP) | VAF 46/697 reads (7%) | called by muse, mutect2
- KIAA1549 | c.4404C>T p.H1468= | Silent (SNP) | VAF 40/505 reads (8%) | catalogued as rs543122883; called by muse, mutect2
- NOS1 | c.3180G>A p.P1060= | Silent (SNP) | VAF 75/484 reads (15%) | catalogued as rs955465487, COSV57613185; called by muse, mutect2, varscan2
- PM20D1 | c.1104G>A p.Q368= | Silent (SNP) | VAF 147/339 reads (43%) | called by muse, mutect2, varscan2
- THSD7B | c.2004G>A p.S668= | Silent (SNP) | VAF 142/326 reads (44%) | catalogued as rs1379083181, COSV99750078; called by muse, mutect2, varscan2
- Z99774.2 | chr22:26672605 G>T | 3'Flank (SNP) | VAF 27/338 reads (8%) | called by muse, mutect2
